Somatic mutation profile of tumor specimen TARGET-20-PARLGT-09A (aliquot TARGET-20-PARLGT-09A-01D) from TARGET case TARGET-20-PARLGT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.3 years (4,870 days).
Specimen TARGET-20-PARLGT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e33a48c8-8e96-443c-8044-abbbcefe823d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLGT-14A (Bone Marrow Normal), aliquot TARGET-20-PARLGT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/025a80a0-602a-4cdb-8e78-b3f5abdc171a

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs397507505, CM044250, CM060441, COSV61007800; ClinVar: pathogenic; called by muse, mutect2
- CEBPA | c.247del p.Q83Sfs*77 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as COSV57200140; called by mutect2, varscan2
- CEBPA | c.878_880del p.N293del | In Frame Del (DEL) | VAF 33/91 reads (36%) | called by pindel, varscan2
